Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADW, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADW-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Left hemihepatectomy

Organs: Liver (15.5 x 10.0x 4.5 cm and 294.0 gm)

Lesion:

A well-defined multinodular pale tan firm and solid mass
(4.3 x 2.3 x 4.0 cm)

Gross type:

HCC: Multinodular confluent

Resection margin:

Not involved grossly (safety margin: 1.5 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Representative sections submitted

Gross photo: Present

Blocks

T1a,T1b,T1c,T1d,T2-3,TB, tumor mass x 7

L,NB, liver parenchyma x 2

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q405/20/14

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation III

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Complete capsule

Septum formation: No

Surgical resection margin invasion: No/ safety margin: 1.5 cm

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma, moderately differentiated, cirrhosis

T56000, P10, M81703, moderately differentiated, M49500

DIAGNOSIS:

Liver, left lobe, left hemihepatectomy:

[page 2 of 2]
Hepatocellular carcinoma, moderately differentiated
Cirrhosis, mixed

Suggestion :

Source: NCI Genomic Data Commons file c0283eda-08ec-4043-b4ae-a089ba52bd17 (TCGA-DD-AADW.18DA1A83-81E4-462C-AA58-FBB1298F86F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).